CCDI case PBCMCW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7ab913c9-f490-4be0-be15-d7ee27bffe1f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.7 years (7,180 days).

Biospecimens (2 samples)
- Sample 0DV14P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV15C: Tissue type: Tumor; Specimen type: Solid Tissue.
